Somatic mutation profile of tumor specimen BA2510D (aliquot aq-BA2510D) from BEATAML1.0 case 2073, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.5 years (23,941 days).
Specimen BA2510D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5dd9997b-d30c-4e40-878e-c0f813585fe0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2328D (Solid Tissue Normal), aliquot aq-BA2328D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31a3c8d8-4990-4547-8f1a-79d057856ecf

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AAK1 | c.394G>T p.G132C | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NKIRAS2 | c.286C>A p.R96S | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.069); called by muse, mutect2
- OLIG2 | c.888C>A p.S296R | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.121); called by muse, mutect2
- SCN11A | c.1694G>T p.C565F | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.04); called by muse, mutect2
- SLC6A16 | c.353G>T p.G118V | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
